Somatic mutation profile of tumor specimen C3L-00161-01 (aliquot CPT0070380007) from CPTAC case C3L-00161, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 46.2 years (16,864 days).
Specimen C3L-00161-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89788207-3435-4b03-9247-6c2e1d12e96a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00161-31 (Blood Derived Normal), aliquot CPT0070970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deed889b-dcbd-46a7-98f6-e4980eff4283

The open-access MAF lists 1,146 somatic variants for this specimen: 760 protein-altering or splice-affecting, 221 silent, 165 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 499, Silent 221, Frame Shift Del 162, Intron 85, Nonsense Mutation 31, Frame Shift Ins 29, 3'UTR 26, 5'UTR 14, Splice Region 14, 5'Flank 14, Splice Site 13, RNA 13.

Variants (750 of 1,146; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- CHEK2 | c.1005dup p.D336* (on ENST00000382580 / NM_001005735.2; = p.D293* on NM_007194.4) | Frame Shift Ins (INS) | VAF 47/156 reads (30%) | catalogued as rs772683219; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CP | c.146+1G>A p.X49_splice | Splice Site (SNP) | VAF 25/109 reads (23%) | catalogued as rs386134134, CS044258; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.5961del p.E1988Rfs*42 | Frame Shift Del (DEL) | VAF 41/143 reads (29%) | catalogued as rs387906460, CD062157, CD961984; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GNAT2 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 101/372 reads (27%) | catalogued as rs748981899, CM110693; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ITGA7 | c.1220del p.G407Vfs*143 (on ENST00000555728; = p.G363Vfs*143 on NM_002206.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | catalogued as rs587780362, COSV57691242, COSV57699409; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 90/256 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PAFAH1B1 | c.162del p.K54Nfs*15 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | catalogued as rs113994198; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 56/168 reads (33%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749415085, COSV55874617, COSV55892918, COSV55900319; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1300-1G>T p.X434_splice (on ENST00000521381 / NM_181523.3; = p.X164_splice on NM_181504.4) | Splice Site (SNP) | VAF 13/40 reads (33%) | hotspot (GDC flag); catalogued as COSV57135007, COSV99160385; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 161/297 reads (54%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RYR1 | c.4094del p.G1365Efs*33 | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs587784375, COSV62107582; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 23/58 reads (40%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- ABCA7 | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.513); catalogued as rs756112727; called by muse, mutect2, varscan2
- ABCD1 | c.1478T>C p.L493P | Missense Mutation (SNP) | VAF 71/273 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as CM118164; called by muse, mutect2, varscan2
- AC068580.4 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 72/287 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.179); catalogued as rs772976217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC138647.1 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1419741733; called by muse, mutect2
- ACSBG1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as rs573692044, COSV51906319; called by muse, mutect2, varscan2
- ADAM12 | c.2168C>T p.A723V | Missense Mutation (SNP) | VAF 14/255 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.221); catalogued as COSV64104036; called by muse, mutect2
- ADAMTS3 | c.1192C>A p.H398N | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV99711215, COSV99712391; called by muse, mutect2, varscan2
- ADGRG4 | c.6516G>T p.K2172N | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs145864422; called by muse, mutect2, varscan2
- ADGRG5 | c.608del p.G203Afs*62 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | catalogued as rs750862917; called by mutect2, pindel, varscan2
- ADK | c.346C>A p.L116M (on ENST00000286621; = p.L99M on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/337 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.676); catalogued as rs769185684, COSV99691968; called by muse, mutect2
- AEBP1 | c.2383del p.E795Rfs*32 | Frame Shift Del (DEL) | VAF 47/183 reads (26%) | catalogued as COSV56260153; called by mutect2, pindel, varscan2
- AFF3 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 19/402 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1436498219; called by muse, mutect2
- AGBL5 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs755544280, COSV59935848; called by muse, mutect2, varscan2
- AHNAK2 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs765118666; called by muse, mutect2, varscan2
- ALS2CL | c.2600C>T p.T867M | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74585038, COSV59674654; called by muse, mutect2, varscan2
- ALX3 | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs765747640; called by muse, mutect2, varscan2
- AMD1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.89); catalogued as rs772906873; called by muse, varscan2
- ANKRD11 | c.7355G>A p.R2452H | Missense Mutation (SNP) | VAF 88/356 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781584370; called by muse, mutect2, varscan2
- ANKRD53 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs1553424434, COSV55538209; called by muse, mutect2
- ANKRD60 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189070946; called by muse, mutect2, varscan2
- ANO1 | c.2873C>T p.P958L | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs770219157; called by muse, mutect2, varscan2
- APBB2 | c.955C>T p.R319W (on ENST00000295974 / NM_001166050.2; = p.R320W on NM_004307.2) | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs538682911, COSV55954670; called by muse, mutect2, varscan2
- APP | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 104/370 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as rs201045185; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQP11 | c.254_256del p.F85del | In Frame Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs747275160; called by pindel, varscan2
- AQP8 | c.363del p.M122Cfs*10 | Frame Shift Del (DEL) | VAF 12/117 reads (10%) | catalogued as rs759782104; called by mutect2, varscan2
- ARHGAP25 | c.604C>T p.P202S (on ENST00000409202 / NM_001007231.3; = p.P194S on NM_014882.3) | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs370502215; called by muse, mutect2, varscan2
- ARHGAP31 | c.4013G>T p.R1338M | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775555581; called by muse, mutect2, varscan2
- ARHGAP45 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs201907876, COSV54037266; called by muse, mutect2, varscan2
- ARHGEF10L | c.2660C>T p.S887L | Missense Mutation (SNP) | VAF 90/203 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as rs912875134; called by muse, mutect2, varscan2
- ARHGEF9 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.097); catalogued as rs1203752009, COSV53637533; called by muse, mutect2
- ARID1A | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 81/261 reads (31%) | catalogued as COSV61377632; called by muse, mutect2, varscan2
- ARSD | c.992G>A p.W331* | Nonsense Mutation (SNP) | VAF 41/114 reads (36%) | catalogued as rs111939179, COSV54198347; called by muse, mutect2, varscan2
- ASB12 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1298256142, COSV62856916; called by muse, mutect2, varscan2
- ASMTL | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.018); catalogued as rs374787639, COSV67243452; called by muse, mutect2
- ATAD1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.741); catalogued as rs1302126882; called by muse, mutect2, varscan2
- ATP13A2 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 134/395 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs759534355, COSV100454484, COSV58704952; called by muse, mutect2, varscan2
- ATP1A1 | c.297dup p.F100Vfs*17 | Frame Shift Ins (INS) | VAF 97/291 reads (33%) | catalogued as rs1360019202; called by mutect2, pindel, varscan2
- ATP6V1G3 | c.83-2A>G p.X28_splice | Splice Site (SNP) | VAF 23/84 reads (27%) | catalogued as rs930811221; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- ATXN1L | c.1506del p.L503* | Frame Shift Del (DEL) | VAF 28/123 reads (23%) | catalogued as COSV101449132; called by mutect2, pindel, varscan2
- ATXN2 | c.3838G>A p.A1280T (on ENST00000550104; = p.A1120T on NM_002973.4) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs749624885; called by muse, mutect2, varscan2
- B3GNT6 | c.293G>A p.C98Y | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542860457; called by muse, mutect2, varscan2
- B4GALT7 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs568792091; called by muse, mutect2, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | catalogued as COSV59620972; called by mutect2, varscan2
- BAG3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 110/342 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755525021; called by muse, mutect2, varscan2
- BBS4 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 25/348 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs969384648, COSV51439185; called by muse, mutect2
- BICRA | c.934del p.A312Pfs*31 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs1341478903; called by mutect2, pindel, varscan2
- BMP15 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.328); catalogued as rs781848548, COSV53140331; called by muse, mutect2
- BNC2 | c.863G>T p.S288I | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV66141061; called by muse, mutect2, varscan2
- BRAP | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs770360667, COSV59537000; called by muse, mutect2, varscan2
- BSN | c.4222C>T p.R1408C | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs143474442, COSV99609730; called by muse, mutect2, varscan2
- BTBD2 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754684263, COSV55308867; called by muse, mutect2, varscan2
- BTBD8 | c.1886del p.N629Mfs*9 (on ENST00000636805 / NM_001376131.1; = p.N116Mfs*9 on NM_015237.4) | Frame Shift Del (DEL) | VAF 43/167 reads (26%) | catalogued as rs774107642; called by mutect2, pindel, varscan2
- C10orf67 | c.311C>T p.T104M (on ENST00000323327; = p.T105M on NM_153714.3) | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs368235615; called by muse, mutect2, varscan2
- C15orf62 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as rs1201235872; called by muse, mutect2
- C21orf62 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 52/185 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as rs148054755, COSV66672227; called by muse, mutect2, varscan2
- C4A | c.3163C>T p.R1055W | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs750422695; called by muse, mutect2
- C8orf58 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs373734103, COSV99254423; called by muse, mutect2, varscan2
- C9orf78 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs140049867; called by muse, mutect2, varscan2
- CACNA1F | c.3866G>A p.R1289H | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs782330306; called by muse, mutect2
- CADPS | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 79/215 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as rs1433222269; called by muse, mutect2, varscan2
- CARD11 | c.2158C>T p.R720* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV62755287; called by muse, mutect2, varscan2
- CCDC170 | c.1914del p.K638Nfs*24 | Frame Shift Del (DEL) | VAF 95/265 reads (36%) | catalogued as rs751612825; called by mutect2, pindel, varscan2
- CCDC66 | c.1435C>T p.R479C (on ENST00000394672 / NM_001353147.1; = p.R445C on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs747923760; called by muse, mutect2, varscan2
- CCDC73 | c.3196dup p.R1066Kfs*17 | Frame Shift Ins (INS) | VAF 20/110 reads (18%) | catalogued as rs781654336; called by mutect2, pindel, varscan2
- CCDC9 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745548599; called by muse, mutect2, varscan2
- CCDC97 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs200358934; called by muse, mutect2, varscan2
- CCND1 | c.869T>A p.V290E | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57121427; called by mutect2, varscan2
- CDCA2 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144313074, COSV57949661; called by muse, mutect2, varscan2
- CDHR5 | c.1484G>A p.G495D (on ENST00000358353 / NM_001171968.2; = p.G501D on NM_021924.5) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs538177063; called by muse, mutect2, varscan2
- CDYL | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV61038822; called by muse, mutect2, varscan2
- CELSR2 | c.5267G>A p.R1756H | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs142723500; called by muse, mutect2, varscan2
- CEMIP | c.2590G>A p.G864R | Missense Mutation (SNP) | VAF 122/401 reads (30%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.974); catalogued as rs374325479; called by muse, mutect2, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CHD5 | c.3452G>A p.R1151Q | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52408505; called by muse, mutect2, varscan2
- CHGB | c.630del p.E211Rfs*3 | Frame Shift Del (DEL) | VAF 38/153 reads (25%) | catalogued as rs1568551915; called by mutect2, varscan2
- CHTF18 | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs777874656; called by muse, mutect2, varscan2
- CLDN9 | c.537del p.L180Sfs*196 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | catalogued as rs763852712; called by mutect2, pindel, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 42/103 reads (41%) | catalogued as rs369752219; called by mutect2, varscan2
- CMTM1 | c.180dup p.I61Yfs*21 (on ENST00000457188 / NM_181269.3; = p.I178Yfs*21 on NM_052999.4) | Frame Shift Ins (INS) | VAF 20/70 reads (29%) | catalogued as rs773521289; called by mutect2, varscan2
- CNTN1 | c.2665T>C p.C889R | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as COSV61636339; called by muse, mutect2
- CNTNAP2 | c.2956G>A p.G986S | Missense Mutation (SNP) | VAF 90/324 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs751542883, COSV62168175; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COBL | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs753468538; called by muse, mutect2, varscan2
- COL11A2 | c.2326C>T p.R776C (on ENST00000341947 / NM_080680.3; = p.R669C on NM_080679.2) | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776701792, COSV59493332; called by muse, mutect2
- CORO1B | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as rs767771419, COSV57049917; called by muse, varscan2
- CPD | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749699085, COSV56710431, COSV56716470; called by muse, mutect2, varscan2
- CPT1B | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs778663440, COSV100376804; called by muse, mutect2, varscan2
- CSMD3 | c.9746T>C p.F3249S (on ENST00000297405 / NM_001363185.1; = p.F3080S on NM_052900.3) | Missense Mutation (SNP) | VAF 75/282 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as COSV52313180; called by muse, mutect2, varscan2
- CSPG5 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776965190; called by muse, mutect2, varscan2
- CTCF | c.1348del p.S450Vfs*61 | Frame Shift Del (DEL) | VAF 47/168 reads (28%) | catalogued as rs34679888; called by mutect2, pindel, varscan2
- CTSW | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs140611694; called by muse, mutect2, varscan2
- CTSW | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.806); catalogued as rs760246700, COSV57171945; called by muse, mutect2, varscan2
- CUBN | c.6244G>A p.A2082T | Missense Mutation (SNP) | VAF 87/388 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.136); catalogued as rs1340099685; called by muse, mutect2, varscan2
- CYFIP2 | c.3368G>A p.R1123H (on ENST00000616178 / NM_001291722.2; = p.R1098H on NM_014376.4) | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs748704223, COSV59046906; called by muse, mutect2, varscan2
- DAPL1 | c.127del p.T43Qfs*21 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | catalogued as rs763165810; called by mutect2, pindel, varscan2
- DEF6 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 93/226 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.664); catalogued as rs754987228, COSV57354568; called by muse, mutect2, varscan2
- DGKD | c.2564dup p.T856Yfs*5 (on ENST00000264057 / NM_152879.3; = p.T812Yfs*5 on NM_003648.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | catalogued as rs35538077; called by mutect2, varscan2
- DHODH | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 106/360 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54663733; called by muse, mutect2, varscan2
- DHRS7C | c.889G>A p.V297M (on ENST00000330255 / NM_001220493.2; = p.V296M on NM_001105571.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1490495059; called by muse, mutect2, varscan2
- DLL1 | c.1642G>A p.V548M | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs568359643, COSV64538920; called by muse, mutect2, varscan2
- DMAC1 | c.236del p.P79Rfs*59 | Frame Shift Del (DEL) | VAF 39/174 reads (22%) | catalogued as rs778030114, COSV64065840; called by mutect2, pindel, varscan2
- DNAJC10 | c.849+3A>G | Splice Region (SNP) | VAF 11/145 reads (8%) | catalogued as rs1166656895; called by muse, mutect2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DUS2 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277433054, COSV99076145; called by muse, mutect2, varscan2
- DYNC2I1 | c.2663G>A p.G888D | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV68106802; called by muse, mutect2
- DYSF | c.5198T>C p.I1733T | Missense Mutation (SNP) | VAF 19/262 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs866367366; ClinVar: uncertain significance; called by muse, mutect2
- ECM2 | c.30dup p.L11Sfs*8 | Frame Shift Ins (INS) | VAF 16/88 reads (18%) | catalogued as rs752987091; called by mutect2, varscan2
- EIF3A | c.3439C>T p.R1147C | Missense Mutation (SNP) | VAF 106/303 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs202128409; called by muse, varscan2
- EML5 | c.5135C>T p.A1712V (on ENST00000380664; = p.A1720V on NM_183387.3) | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1304806983; called by muse, mutect2, varscan2
- EML6 | c.3456del p.F1152Lfs*10 | Frame Shift Del (DEL) | VAF 40/142 reads (28%) | catalogued as rs745447718; called by mutect2, varscan2
- EPHX4 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV64889613; called by muse, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 12/50 reads (24%) | catalogued as rs768793415; called by mutect2, varscan2
- ERC2 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs750451019, COSV55603699; called by muse, mutect2, varscan2
- ERMP1 | c.1951dup p.T651Nfs*25 | Frame Shift Ins (INS) | VAF 21/80 reads (26%) | catalogued as rs753821453; called by mutect2, varscan2
- ERP44 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as COSV52435769; called by muse, mutect2
- ESYT1 | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs774943544; called by muse, mutect2, varscan2
- ETNPPL | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56596224; called by muse, mutect2, varscan2
- EYA4 | c.1241G>A p.R414H (on ENST00000531901 / NM_001301013.1; = p.R408H on NM_004100.5) | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs760787542, COSV62047993, COSV62049072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM135B | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200240655; called by muse, mutect2, varscan2
- FAM227A | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1025267794; called by muse, mutect2, varscan2
- FAM234B | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as rs759896574, COSV99545746; called by muse, mutect2, varscan2
- FAM71F2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs757554559; called by mutect2, varscan2
- FAT3 | c.4200dup p.X1400_splice | Splice Site (INS) | VAF 15/82 reads (18%) | catalogued as rs1160251707; called by mutect2, pindel, varscan2
- FBLN1 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1569239672, COSV53044710; called by muse, mutect2, varscan2
- FFAR4 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs138801183; called by muse, mutect2, varscan2
- FLG2 | c.5003C>T p.T1668I | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.114); catalogued as rs1366853210; called by muse, mutect2, varscan2
- FNBP1 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760309443, COSV63090348; called by muse, mutect2, varscan2
- FOXS1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs146098503; called by muse, mutect2, varscan2
- FSTL4 | c.862A>G p.T288A | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1345157521, COSV54763498; called by muse, mutect2, varscan2
- FUT1 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 95/271 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV59569113; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 32/115 reads (28%) | catalogued as rs756304971; called by mutect2, varscan2
- GABBR1 | c.1721del p.P574Qfs*32 | Frame Shift Del (DEL) | VAF 39/120 reads (33%) | catalogued as rs777471402; called by mutect2, pindel, varscan2
- GBP6 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs116036340; called by muse, mutect2, varscan2
- GGT5 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1026801373, COSV54068813; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | catalogued as rs750227570; called by mutect2, varscan2
- GLI2 | c.1597C>T p.R533C (on ENST00000361492 / NM_001374353.1; = p.R550C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs564753456; called by muse, mutect2, varscan2
- GLI3 | c.2969G>A p.R990H | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs1224363568; called by muse, mutect2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 32/81 reads (40%) | catalogued as rs749150409; called by mutect2, varscan2
- GPHN | c.1314+4C>T | Splice Region (SNP) | VAF 103/303 reads (34%) | catalogued as rs759514847, COSV100017958; called by muse, mutect2, varscan2
- GRIK3 | c.2383A>G p.M795V | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs989970604, COSV66137296; called by muse, mutect2, varscan2
- GRIK5 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as rs781838864; called by muse, mutect2
- GRIN3B | c.683del p.G228Vfs*129 | Frame Shift Del (DEL) | VAF 41/119 reads (34%) | catalogued as rs1182407511; called by mutect2, pindel, varscan2
- GRM2 | c.617_618del p.Y206Cfs*7 | Frame Shift Del (DEL) | VAF 70/319 reads (22%) | catalogued as rs1559693974; called by mutect2, pindel, varscan2
- GSDME | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 78/276 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs369233573; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 20/55 reads (36%) | catalogued as rs754199513; called by mutect2, varscan2
- GSX1 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs576086958, COSV100262498; called by muse, mutect2, varscan2
- H1-1 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 86/352 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs776390963, COSV55119404; called by muse, mutect2, varscan2
- H1-7 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs550344470, COSV58602049; called by muse, mutect2, varscan2
- HAX1 | c.173del p.P58Lfs*27 | Frame Shift Del (DEL) | VAF 97/320 reads (30%) | catalogued as rs758657008; called by mutect2, varscan2
- HCAR2 | c.664C>T p.R222W | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs146071786, COSV100186553; called by muse, mutect2, varscan2
- HCK | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs765715998, COSV52946751; called by muse, mutect2, varscan2
- HERC6 | c.1156A>G p.M386V | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs745705833; called by muse, mutect2, varscan2
- HMCN2 | c.13675C>T p.R4559C | Missense Mutation (SNP) | VAF 101/322 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs939740584; called by muse, mutect2, varscan2
- HMGXB3 | c.4013G>A p.R1338H (on ENST00000613459; = p.R1092H on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 131/354 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs939697024; called by muse, mutect2, varscan2
- HNRNPL | c.1002del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as COSV99670288; called by mutect2, pindel, varscan2
- HOOK2 | c.1586del p.G529Afs*11 | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | catalogued as rs768806444; called by mutect2, pindel, varscan2
- HOXD3 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99980510; called by muse, mutect2, varscan2
- HPCAL1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs373345229; called by muse, mutect2, varscan2
- IFI16 | c.679del p.I227* | Frame Shift Del (DEL) | VAF 77/284 reads (27%) | catalogued as rs1438972404; called by mutect2, pindel, varscan2
- IFI44 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs758548967, COSV66074739; called by muse, mutect2, varscan2
- IFNGR1 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 28/418 reads (7%) | catalogued as COSV100880472; called by muse, mutect2
- IFNL3 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1349364744; called by muse, mutect2, varscan2
- IL12RB2 | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 77/293 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); catalogued as rs200772326; called by muse, mutect2, varscan2
- INCENP | c.1937G>A p.R646H (on ENST00000394818 / NM_001040694.2; = p.R642H on NM_020238.3) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs371297887; called by muse, mutect2, varscan2
- INPP1 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.394); catalogued as rs755770972, COSV100487250; called by muse, mutect2, varscan2
- IQSEC2 | c.1084C>A p.R362S (on ENST00000642864 / NM_001111125.3; = p.R157S on NM_015075.2) | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs1009285975; called by muse, mutect2, varscan2
- IRF8 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 111/328 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs767204633, COSV99236729; called by muse, mutect2, varscan2
- ISOC1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs1296193380; called by muse, mutect2, varscan2
- ITFG2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs903717969, COSV57389040; called by muse, mutect2, varscan2
- ITIH3 | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs770349939; called by muse, mutect2, varscan2
- JAM3 | c.745del p.V249Ffs*10 | Frame Shift Del (DEL) | VAF 97/410 reads (24%) | catalogued as rs763250381; called by mutect2, pindel, varscan2
- KAT2A | c.1681G>A p.G561S | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs782626676, COSV52424922; called by muse, mutect2, varscan2
- KCNA6 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99768257; called by muse, mutect2, varscan2
- KCNAB3 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.719); catalogued as rs556184782; called by muse, mutect2, varscan2
- KCNC3 | c.1880del p.G627Efs*27 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | catalogued as rs1159900432; called by mutect2, pindel, varscan2
- KCNH4 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 71/227 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs770352849; called by muse, mutect2, varscan2
- KCNH4 | c.642del p.S215Lfs*62 | Frame Shift Del (DEL) | VAF 54/162 reads (33%) | catalogued as COSV99236896; called by mutect2, pindel, varscan2
- KCNV2 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 32/595 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs143664586; called by muse, mutect2
- KCP | c.3568G>A p.V1190M (on ENST00000620378; = p.V1314M on NM_001366122.1) | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1183776703; called by muse, mutect2, varscan2
- KCTD8 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.067); catalogued as COSV63593724; called by muse, mutect2, varscan2
- KDM2A | c.2197del p.R733Gfs*4 | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | catalogued as rs774459181, COSV58189176; called by mutect2, varscan2
- KIAA1549 | c.3913G>A p.V1305M | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373413285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF20B | c.5443C>T p.R1815* (on ENST00000371728 / NM_001284259.2; = p.R1775* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 29/114 reads (25%) | catalogued as rs202099671; called by muse, mutect2, varscan2
- KLHL22 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs758974070, COSV61022455; called by muse, mutect2, varscan2
- KLHL32 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756561892, COSV65113428; called by muse, mutect2, varscan2
- KMT2D | c.12076C>T p.Q4026* | Nonsense Mutation (SNP) | VAF 23/331 reads (7%) | catalogued as CM114122; called by muse, mutect2
- LAMB1 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99739756; called by muse, mutect2, varscan2
- LAMC3 | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144930767, COSV63091766; called by muse, mutect2, varscan2
- LCAT | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 107/276 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1380009545, CM043857, COSV50452203; called by muse, mutect2, varscan2
- LCE1C | c.305del p.G102Afs*45 | Frame Shift Del (DEL) | VAF 37/117 reads (32%) | catalogued as rs765643412; called by mutect2, pindel
- LGR4 | c.2782C>T p.R928* | Nonsense Mutation (SNP) | VAF 34/98 reads (35%) | catalogued as rs1461413137, COSV58725333; called by muse, mutect2, varscan2
- LIG1 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs564476088, COSV54393475; called by muse, mutect2, varscan2
- LMLN | c.1597G>A p.V533I | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs766995264, COSV57597982; called by muse, mutect2, varscan2
- LOXHD1 | c.5225G>A p.R1742H (on ENST00000642948; = p.R631H on NM_001145472.3) | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1248383250; called by muse, varscan2
- LRATD1 | c.176del p.P59Rfs*41 | Frame Shift Del (DEL) | VAF 30/127 reads (24%) | catalogued as COSV54472034, COSV99707096; called by mutect2, varscan2
- LRCH4 | c.1865G>A p.C622Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99776136; called by muse, mutect2
- LRIG2 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs776956140; called by muse, mutect2, varscan2
- LRP6 | c.3277C>T p.R1093W | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752896710, COSV53789294; called by muse, mutect2, varscan2
- LRPAP1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372003322; called by muse, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 26/102 reads (25%) | catalogued as rs752439249; called by mutect2, varscan2
- MAD2L2 | c.553del p.R185Gfs*2 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as COSV99336155; called by mutect2, pindel
- MAGI1 | c.3902C>T p.P1301L | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1313003987, COSV58340124; called by muse, mutect2
- MAML1 | c.2890C>T p.R964W | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746302193; called by muse, mutect2, varscan2
- MARF1 | c.4042C>T p.R1348W | Missense Mutation (SNP) | VAF 75/258 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1416076158, COSV60023513; called by muse, varscan2
- MCEE | c.419dup p.K141Efs*7 | Frame Shift Ins (INS) | VAF 66/280 reads (24%) | catalogued as rs776473131; called by mutect2, varscan2
- MCM2 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs751729409, COSV54032639; called by muse, mutect2, varscan2
- MCPH1 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 13/250 reads (5%) | catalogued as COSV60913936; called by muse, mutect2
- MDC1 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs753023149; called by muse, mutect2, varscan2
- MED12 | c.2430G>T p.E810D | Missense Mutation (SNP) | VAF 65/269 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100378617; called by muse, mutect2, varscan2
- MED24 | c.2270G>A p.R757Q | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs147398856; called by muse, mutect2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | catalogued as rs745558596; called by pindel, varscan2
- MFAP1 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51038719; called by muse, mutect2, varscan2
- MINAR1 | c.1734G>T p.K578N | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as COSV100548963, COSV59587258; called by muse, mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 33/99 reads (33%) | catalogued as rs750307488; called by mutect2, varscan2
- MPDZ | c.5912C>T p.T1971M (on ENST00000319217 / NM_001330637.2; = p.T1942M on NM_003829.5) | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs981939723; called by muse, mutect2, varscan2
- MUC12 | c.11360C>T p.T3787M (on ENST00000379442; = p.T3644M on NM_001164462.1) | Missense Mutation (SNP) | VAF 103/739 reads (14%) | SIFT deleterious (0.04); catalogued as rs1278033608; called by muse, varscan2
- MUC19 | c.461del p.K154Sfs*87 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs537060918; called by mutect2, varscan2
- MYLK | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs758715543; ClinVar: uncertain significance; called by muse, mutect2
- MYOF | c.4216G>A p.A1406T | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs370235457; called by muse, mutect2, varscan2
- NAA80 | c.734del p.P245Lfs*7 (on ENST00000417393 / NM_001200018.2; = p.P267Lfs*7 on NM_012191.4) | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs34185226; called by mutect2, pindel
- NAGPA | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | PolyPhen benign (0.154); catalogued as rs757955863; called by muse, mutect2, varscan2
- NBEA | c.1623G>A p.M541I | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV59778904; called by muse, mutect2, varscan2
- NCK2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV51893743; called by muse, mutect2, varscan2
- NCOR2 | c.3178del p.R1060Vfs*3 | Frame Shift Del (DEL) | VAF 4/10 reads (40%) | catalogued as rs749518211, COSV100656528, COSV62300840; called by mutect2, varscan2
- NDST1 | c.2152C>T p.R718* | Nonsense Mutation (SNP) | VAF 93/339 reads (27%) | catalogued as rs1302728109; called by muse, mutect2, varscan2
- NDUFA10 | c.604dup p.H202Pfs*25 | Frame Shift Ins (INS) | VAF 82/240 reads (34%) | catalogued as rs746019378; ClinVar: uncertain significance; called by mutect2, varscan2
- NEUROD1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 153/421 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM161575; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 38/129 reads (29%) | catalogued as rs145147241; called by mutect2, varscan2
- NKD1 | c.862del p.R288Afs*59 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs772439983; called by mutect2, pindel
- NKX6-1 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs778694904, COSV55685323; called by muse, varscan2
- NMRK1 | c.389+3A>G | Splice Region (SNP) | VAF 24/100 reads (24%) | catalogued as COSV63112320; called by muse, varscan2
- NOS1 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs773636678, COSV57613169; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | catalogued as rs776154715; called by mutect2, varscan2
- NTSR1 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs772996912, COSV65138478; called by muse, varscan2
- NXPH2 | c.520del p.Q174Sfs*107 | Frame Shift Del (DEL) | VAF 51/187 reads (27%) | catalogued as rs1558909514, COSV55642935; called by mutect2, pindel, varscan2
- OBSCN | c.23086C>T p.R7696W | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs541725106, COSV63001241; called by muse, mutect2, varscan2
- ODF3L2 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs150637619; called by muse, mutect2, varscan2
- OR2D3 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV99049379; called by muse, mutect2
- OR2D3 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs138058537; called by muse, varscan2
- OR4D6 | c.777C>A p.C259* | Nonsense Mutation (SNP) | VAF 8/128 reads (6%) | catalogued as rs965279738; called by muse, mutect2
- OR51D1 | c.117G>A p.W39* | Nonsense Mutation (SNP) | VAF 10/256 reads (4%) | catalogued as COSV62914263; called by muse, mutect2
- OR6C65 | c.305dup p.L102Ffs*18 | Frame Shift Ins (INS) | VAF 16/74 reads (22%) | catalogued as rs753853776; called by mutect2, varscan2
- OTUD7B | c.2282G>A p.R761K | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.022); catalogued as COSV100967428, COSV100967453; called by muse, mutect2, varscan2
- PALD1 | c.1900dup p.R634Pfs*6 | Frame Shift Ins (INS) | VAF 22/77 reads (29%) | catalogued as rs745381684; called by mutect2, pindel, varscan2
- PAPPA2 | c.1229del p.G410Efs*47 | Frame Shift Del (DEL) | VAF 71/241 reads (29%) | catalogued as COSV62772783; called by mutect2, pindel, varscan2
- PARP12 | c.1847C>T p.T616M | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.373); catalogued as rs776856537, COSV99694026; called by muse, mutect2, varscan2
- PCDH15 | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 24/372 reads (6%) | catalogued as COSV100215476; called by muse, mutect2
- PCDH17 | c.1078del p.A360Rfs*2 | Frame Shift Del (DEL) | VAF 50/189 reads (26%) | catalogued as COSV104428993; called by mutect2, pindel, varscan2
- PCSK5 | c.5136del p.S1713Vfs*39 | Frame Shift Del (DEL) | VAF 31/94 reads (33%) | catalogued as COSV70450505; called by mutect2, pindel, varscan2
- PCSK9 | c.1744C>T p.R582* | Nonsense Mutation (SNP) | VAF 14/150 reads (9%) | catalogued as rs373323910; called by muse, mutect2
- PDE5A | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200619248, COSV53346842; called by muse, mutect2, varscan2
- PDZRN3 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs368761158; called by muse, mutect2, varscan2
- PGAP3 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56130868; called by muse, mutect2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PHGDH | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 74/291 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as rs1032334849, COSV65570245; called by muse, mutect2, varscan2
- PHIP | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768324201, COSV51504515, COSV99244662; called by muse, mutect2, varscan2
- PHOSPHO1 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs1344734987; called by muse, mutect2, varscan2
- PKD1L3 | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs1456223579; called by muse, mutect2, varscan2
- PKD1L3 | c.2162dup p.D722Gfs*15 | Frame Shift Ins (INS) | VAF 51/142 reads (36%) | catalogued as rs1422414699; called by mutect2, pindel, varscan2
- PLCB2 | c.2089C>T p.R697C | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs753456494, COSV53030502, COSV53030598; called by muse, mutect2, varscan2
- PLCB3 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54188234; called by muse, mutect2, varscan2
- PLCL1 | c.404del p.F135Sfs*29 | Frame Shift Del (DEL) | VAF 62/152 reads (41%) | catalogued as COSV70821104; called by mutect2, pindel, varscan2
- PLEC | c.749G>A p.R250H (on ENST00000322810 / NM_201380.4; = p.R140H on NM_000445.5) | Missense Mutation (SNP) | VAF 102/235 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs781884905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNB3 | c.4154C>T p.T1385M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1557063587, COSV62803897; called by muse, mutect2, varscan2
- PNMA8B | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.454); catalogued as rs772922156; called by muse, mutect2, varscan2
- POLR1A | c.4855C>T p.R1619W | Missense Mutation (SNP) | VAF 65/235 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1489364223, COSV55690839; called by muse, mutect2, varscan2
- POMT1 | c.1261del p.L421* | Frame Shift Del (DEL) | VAF 159/575 reads (28%) | catalogued as rs749018170; called by mutect2, pindel, varscan2
- POT1 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62933935; called by muse, mutect2
- PPP2R3B | c.1474G>A p.G492S | Missense Mutation (SNP) | VAF 99/285 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs201641619; called by muse, mutect2, varscan2
- PRAG1 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.903); catalogued as rs751499220, COSV100423012; called by muse, mutect2, varscan2
- PRAMEF1 | c.134G>A p.S45N | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.157); catalogued as rs777697542, COSV100179872; called by muse, mutect2
- PREX2 | c.3251G>A p.R1084Q | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as rs1316821029, COSV55761842, COSV55802142; called by muse, mutect2, varscan2
- PROS1 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs549405539, COSV67777260; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.958G>A p.V320M (on ENST00000352766; = p.V241M on NM_181334.5) | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs562703546, COSV100424711; called by muse, mutect2, varscan2
- PTGDR2 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 64/240 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1298591078, COSV57126299; called by muse, varscan2
- RAB24 | c.381_383del p.E127del | In Frame Del (DEL) | VAF 56/160 reads (35%) | catalogued as rs748441443; called by pindel, varscan2
- RAB3GAP1 | c.2855C>T p.S952F | Missense Mutation (SNP) | VAF 32/514 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1214061174; called by muse, mutect2
- RAF1 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 96/251 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM073296, CM122806, CM152880, COSV52574568, COSV52583046; called by muse, mutect2, varscan2
- RALGPS1 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52222020; called by muse, mutect2, varscan2
- RBM20 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs771764951, COSV65704242; ClinVar: uncertain significance; called by muse, mutect2
- REXO1 | c.2851C>T p.R951W | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs781781514; called by muse, mutect2, varscan2
- RFFL | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs750706436; called by muse, mutect2, varscan2
- RFTN2 | c.1397C>A p.A466E | Missense Mutation (SNP) | VAF 157/394 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV99695413; called by muse, mutect2, varscan2
- RNF123 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs749994548, COSV59685300; called by muse, mutect2, varscan2
- RNF166 | c.337C>T p.H113Y | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1476664381; called by muse, mutect2, varscan2
- RNF213 | c.4537G>A p.A1513T | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1265171104; called by muse, mutect2, varscan2
- ROBO4 | c.570dup p.S191Vfs*11 | Frame Shift Ins (INS) | VAF 13/69 reads (19%) | catalogued as rs749882823; called by mutect2, pindel, varscan2
- RPF1 | c.868_870del p.F290del | In Frame Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs774733749; called by pindel, varscan2
- RTL1 | c.3731G>A p.R1244H | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as rs770846607; called by muse, mutect2, varscan2
- RTN4R | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1332111039; called by muse, mutect2, varscan2
- RUBCN | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs772081815; called by muse, mutect2
- SALL3 | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs773084670, COSV101610006; called by muse, mutect2, varscan2
- SALL3 | c.3314del p.P1105Hfs*81 | Frame Shift Del (DEL) | VAF 35/109 reads (32%) | catalogued as rs749383364; called by mutect2, varscan2
- SAMD11 | c.1237dup p.Q413Pfs*42 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | catalogued as rs1223597129; called by mutect2, varscan2
- SCG2 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs377214328; called by muse, mutect2, varscan2
- SCN2B | c.561del p.E188Sfs*4 | Frame Shift Del (DEL) | VAF 118/383 reads (31%) | catalogued as rs1271094414; called by mutect2, pindel, varscan2
- SCN4A | c.393G>A p.A131= | Splice Region (SNP) | VAF 37/113 reads (33%) | catalogued as rs368874606; called by muse, mutect2, varscan2
- SCN8A | c.3562C>T p.R1188W | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1430513260, COSV61981460; called by muse, mutect2, varscan2
- SEC16B | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 13/120 reads (11%) | catalogued as rs763978372; called by muse, mutect2, varscan2
- SEL1L | c.1110del p.G371Vfs*20 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | catalogued as COSV60921783; called by mutect2, pindel
- SEMA3B | c.735_737del p.F246del | In Frame Del (DEL) | VAF 33/136 reads (24%) | catalogued as rs782088971; called by pindel, varscan2
- SEMA6C | c.2582dup p.A862Cfs*166 | Frame Shift Ins (INS) | VAF 20/57 reads (35%) | catalogued as rs1379310947; called by mutect2, varscan2
- SEMA6C | c.2020G>A p.V674M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.121); catalogued as rs1302728564; called by muse, mutect2, varscan2
- SERPINB6 | c.293T>C p.V98A (on ENST00000612421 / NM_001271823.2; = p.V79A on NM_004568.6) | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as rs780061780; called by muse, mutect2, varscan2
- SETBP1 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.881); catalogued as rs746316826; called by muse, mutect2, varscan2
- SF3A2 | c.995del p.P332Qfs*114 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs771822076; called by pindel, varscan2
- SH3PXD2A | c.1064C>T p.A355V (on ENST00000369774 / NM_001365079.1; = p.A327V on NM_014631.2) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs150202723; called by muse, mutect2, varscan2
- SHC2 | c.659T>C p.M220T | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as rs1363713115; called by muse, mutect2, varscan2
- SIGLEC5 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55781843; called by muse, mutect2, varscan2
- SKIV2L | c.2446dup p.E816Gfs*63 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | catalogued as rs768446878; called by mutect2, pindel
- SLC20A1 | c.640A>G p.M214V | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs201514397; called by muse, mutect2
- SLC25A27 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs1379731591, COSV64927862, COSV64928000; called by muse, mutect2, varscan2
- SLC2A5 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs201668362, COSV66235684; called by muse, varscan2
- SLC35F3 | c.670G>A p.A224T (on ENST00000366617 / NM_001300845.1; = p.A293T on NM_173508.4) | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754200916; called by muse, mutect2, varscan2
- SLC36A1 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.167); catalogued as rs571362914; called by muse, mutect2, varscan2
- SLC9C2 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV100876876; called by muse, mutect2, varscan2
- SMARCA4 | c.2506-4G>A | Splice Region (SNP) | VAF 79/210 reads (38%) | catalogued as rs375670091; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SMARCA4 | c.4345G>A p.E1449K | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.561); catalogued as rs1568528491, COSV60795923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMG1 | c.8276_8278del p.E2759del | In Frame Del (DEL) | VAF 66/162 reads (41%) | catalogued as rs747994041; called by pindel, varscan2
- SMG1 | c.4398T>A p.F1466L | Missense Mutation (SNP) | VAF 51/185 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.827); catalogued as rs1303413456; called by muse, mutect2, varscan2
- SMIM9 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1557270419; called by muse, mutect2
- SOX30 | c.2057G>A p.R686Q | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs752358794; called by muse, mutect2, varscan2
- SOX8 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1261631740; called by muse, varscan2
- SPATS2L | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs555931476, COSV62350740; called by muse, varscan2
- SPHKAP | c.4373G>T p.G1458V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV60870736; called by muse, mutect2, varscan2
- SPNS2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769429663; called by muse, mutect2, varscan2
- SPOUT1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as rs1053784717, COSV63508931; called by muse, mutect2, varscan2
- SPTAN1 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 15/218 reads (7%) | catalogued as COSV63987845; called by muse, mutect2
- SRD5A2 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.033); catalogued as rs1435250396; called by muse, mutect2
- SRL | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 105/259 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as rs775040662, COSV68423262; called by muse, mutect2, varscan2
- SSBP2 | c.282C>T p.Y94= | Splice Region (SNP) | VAF 49/180 reads (27%) | catalogued as rs201909212, COSV57792532; called by muse, mutect2, varscan2
- SULT2B1 | c.887C>T p.A296V (on ENST00000201586 / NM_177973.2; = p.A281V on NM_004605.2) | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1401676374; called by muse, mutect2, varscan2
- SUSD6 | c.585A>T p.R195S | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61365729; called by muse, varscan2
- SYNE1 | c.25135G>A p.E8379K (on ENST00000367255 / NM_182961.4; = p.E8331K on NM_033071.3) | Missense Mutation (SNP) | VAF 157/413 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs531559372, COSV54917425; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNPO | c.2111G>A p.R704H (on ENST00000394243 / NM_001166208.2; = p.R460H on NM_007286.6) | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs748796947, COSV56941417; called by muse, mutect2, varscan2
- SYT17 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs374172730; called by muse, mutect2, varscan2
- TASP1 | c.812G>A p.C271Y | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1221811793; called by muse, mutect2, varscan2
- TCF19 | c.72del p.A25Pfs*72 | Frame Shift Del (DEL) | VAF 115/185 reads (62%) | catalogued as rs751224053; called by mutect2, pindel, varscan2
- TCIRG1 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853151, CM014984, COSV99693738; called by muse, mutect2, varscan2
- TDRD6 | c.2939A>G p.H980R | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780742720, COSV60174707; called by muse, mutect2, varscan2
- TECTA | c.4384C>T p.R1462C | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs727503462; ClinVar: uncertain significance; called by muse, mutect2
- TGFBRAP1 | c.2189C>T p.A730V | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs749002646, COSV51511667; called by muse, mutect2, varscan2
- TICRR | c.3269G>A p.R1090H | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs749665843, COSV51542344; called by muse, mutect2, varscan2
- TJP2 | c.431A>G p.D144G | Missense Mutation (SNP) | VAF 96/333 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs762503120; called by muse, mutect2, varscan2
- TJP3 | c.2484del p.Y830Tfs*64 | Frame Shift Del (DEL) | VAF 72/215 reads (33%) | catalogued as rs748320679, COSV99515633; called by mutect2, varscan2
- TM2D1 | c.103dup p.A35Gfs*13 | Frame Shift Ins (INS) | VAF 20/120 reads (17%) | catalogued as rs781411504; called by mutect2, pindel, varscan2
- TMEM100 | c.296del p.L99Yfs*2 | Frame Shift Del (DEL) | VAF 39/140 reads (28%) | catalogued as rs894486999; called by mutect2, pindel, varscan2
- TMEM132A | c.1975G>A p.G659R (on ENST00000453848 / NM_178031.3; = p.G660R on NM_017870.4) | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.147); catalogued as rs535352288, COSV50001055; called by muse, mutect2, varscan2
- TMEM154 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 89/213 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.242); catalogued as rs1190935115; called by muse, mutect2, varscan2
- TMEM225 | c.464-1G>T p.X155_splice | Splice Site (SNP) | VAF 26/96 reads (27%) | catalogued as COSV100902806; called by muse, mutect2
- TNK2 | c.2042del p.P681Lfs*35 | Frame Shift Del (DEL) | VAF 8/105 reads (8%) | catalogued as rs751137385; called by mutect2, pindel
- TNXB | c.8200C>T p.R2734C (on ENST00000647633; = p.R2487C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747880757, COSV64479841; called by muse, mutect2, varscan2
- TPCN2 | c.2110del p.R704Afs*17 | Frame Shift Del (DEL) | VAF 41/121 reads (34%) | catalogued as COSV99593300; called by mutect2, pindel, varscan2
- TRAPPC10 | c.3168del p.F1056Lfs*6 | Frame Shift Del (DEL) | VAF 25/73 reads (34%) | catalogued as rs35152556; called by mutect2, pindel
- TRAPPC12 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.036); catalogued as rs781758601, COSV60849794; called by muse, mutect2, varscan2
- TRHDE | c.168G>A p.M56I | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV53848841; called by muse, mutect2
- TRIM66 | c.3110G>A p.R1037Q | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.498); catalogued as COSV55124008; called by muse, mutect2
- TRIM66 | c.1829del p.P610Qfs*14 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs1291294102; called by mutect2, varscan2
- TRIM68 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 138/379 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs758373806, COSV56169151; called by muse, mutect2, varscan2
- TRIML1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs756927618; called by muse, mutect2, varscan2
- TRIOBP | c.4436del p.G1479Afs*28 | Frame Shift Del (DEL) | VAF 25/267 reads (9%) | catalogued as rs756145453; called by mutect2, pindel
- TRPS1 | c.962G>A p.R321Q (on ENST00000220888 / NM_001330599.2; = p.R334Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1333947507, COSV55265007, COSV99630222; called by muse, varscan2
- TRPV2 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 27/350 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs200402564; called by muse, mutect2
- TRPV2 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs1263215594, COSV58427534; called by muse, varscan2
- TSPYL1 | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as rs1208055254; called by muse, mutect2
- TSSC4 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs766495604; called by muse, mutect2, varscan2
- TSSK2 | c.825del p.K276Sfs*30 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs764514103; called by mutect2, varscan2
- TTC28 | c.4483G>A p.V1495M | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs779585702; called by muse, mutect2
- TTI1 | c.2605C>T p.R869C | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141463873; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 68/108 reads (63%) | catalogued as rs767420916; called by mutect2, varscan2
- USH2A | c.8036A>G p.H2679R | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); catalogued as COSV100227282; called by muse, mutect2
- USP29 | c.2279C>T p.A760V | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.342); catalogued as rs1427622094; called by muse, mutect2, varscan2
- USP30 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs565440888, COSV57448996, COSV57452069; called by muse, mutect2, varscan2
- UTP14A | c.1205A>G p.H402R | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1424786865; called by muse, mutect2, varscan2
- UTRN | c.4910G>A p.R1637H | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs765079525; called by muse, mutect2, varscan2
- VCAN | c.8453C>T p.A2818V | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs753597820, COSV54105649; called by muse, mutect2, varscan2
- VIRMA | c.2819T>C p.V940A | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs770093691; called by muse, mutect2, varscan2
- VPS13A | c.3601G>A p.A1201T | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as rs776924250, COSV62437565; called by muse, mutect2, varscan2
- VWA1 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs866498584; called by muse, mutect2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 26/143 reads (18%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WFIKKN2 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs767816747; called by muse, mutect2, varscan2
- WNK4 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99890011; called by muse, mutect2
- XIAP | c.713G>C p.R238P | Missense Mutation (SNP) | VAF 57/314 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV63021954; called by muse, mutect2, varscan2
- XRN2 | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs6047420; called by muse, mutect2, varscan2
- YEATS2 | c.3638C>T p.P1213L | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs750170176; called by muse, mutect2, varscan2
- ZBTB10 | c.335del p.G112Afs*4 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs745788619; called by mutect2, pindel, varscan2
- ZBTB46 | c.1656_1658del p.D552del | In Frame Del (DEL) | VAF 38/187 reads (20%) | catalogued as rs1337573539; called by pindel, varscan2
- ZC3HAV1 | c.435del p.F145Lfs*49 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | catalogued as rs1363033923; called by mutect2, pindel, varscan2
- ZFHX4 | c.9654dup p.E3219Rfs*17 | Frame Shift Ins (INS) | VAF 44/145 reads (30%) | catalogued as rs1219274378, COSV99256254; called by mutect2, pindel, varscan2
- ZFP36L1 | c.812del p.G271Vfs*36 | Frame Shift Del (DEL) | VAF 11/113 reads (10%) | catalogued as rs1421733622; called by mutect2, pindel
- ZNF32 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs769355132; called by muse, mutect2, varscan2
- ZNF384 | c.1542del p.Q514Hfs*35 (on ENST00000361959; = p.Q453Hfs*35 on NM_133476.5) | Frame Shift Del (DEL) | VAF 20/233 reads (9%) | catalogued as COSV58555623; called by mutect2, varscan2*
- ZNF507 | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs573615818; called by muse, mutect2, varscan2
- ZNF536 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.498); catalogued as rs904025179, COSV62823912; called by muse, mutect2, varscan2
- ZNF540 | c.843del p.F281Lfs*4 | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs757107073, COSV57110076; called by mutect2, pindel, varscan2
- ZNF609 | c.4045C>T p.R1349W | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1361713145; called by muse, mutect2, varscan2
- ZNF626 | c.345del p.G116Dfs*3 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | catalogued as rs782441698; called by mutect2, pindel
- ZNF764 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs777409567, COSV53222313; called by muse, mutect2, varscan2
- ABCF1 | c.118del p.T40Rfs*8 | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | called by mutect2, pindel, varscan2
- ACTR6 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- ADGRB2 | c.3131-3del | Splice Region (DEL) | VAF 22/95 reads (23%) | called by mutect2, pindel, varscan2
- ADGRG6 | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.872); called by muse, mutect2
- AGO2 | c.937A>G p.K313E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- AGT | c.1067T>C p.V356A | Missense Mutation (SNP) | VAF 87/308 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- AHCYL1 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.026); called by muse, mutect2
- AHNAK | c.5545C>T p.H1849Y | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2
- AHRR | c.1520T>C p.M507T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALDH4A1 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALKBH5 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ANKRD36B | c.3233A>G p.Q1078R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); called by mutect2, varscan2
- ANO8 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ARAF | c.763del p.R255Gfs*37 | Frame Shift Del (DEL) | VAF 42/100 reads (42%) | called by mutect2, varscan2
- ARHGAP21 | c.1262G>A p.S421N | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2
- ARHGAP30 | c.1588dup p.E530Gfs*45 | Frame Shift Ins (INS) | VAF 46/172 reads (27%) | called by mutect2, pindel, varscan2
- ARHGAP44 | c.1793G>A p.G598D | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ARHGEF26 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2
- ARID1A | c.3349A>T p.I1117F | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ARID1B | c.1235dup p.S413Vfs*122 | Frame Shift Ins (INS) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- ARMC8 | c.1871A>G p.N624S (on ENST00000469044 / NM_001363941.2; = p.N610S on NM_015396.6) | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2
- ARPC5L | c.*6del | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | called by mutect2, varscan2
- ARVCF | c.461del p.P154Hfs*2 | Frame Shift Del (DEL) | VAF 23/69 reads (33%) | called by mutect2, pindel, varscan2
- ATMIN | c.463-1G>A p.X155_splice | Splice Site (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2
- ATP10D | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.179); called by muse, mutect2
- ATP5MD | c.154del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 32/131 reads (24%) | called by mutect2, pindel, varscan2
- BANP | c.484A>T p.I162F (on ENST00000286122; = p.I131F on NM_017869.4) | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- BAZ1B | c.621del p.G208Efs*17 | Frame Shift Del (DEL) | VAF 24/128 reads (19%) | called by mutect2, pindel, varscan2
- BCAR1 | c.1853del p.G618Vfs*84 | Frame Shift Del (DEL) | VAF 13/121 reads (11%) | called by mutect2, pindel
- BEX1 | c.47del p.N16Mfs*51 | Frame Shift Del (DEL) | VAF 11/121 reads (9%) | called by mutect2, pindel
- BNC1 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 53/117 reads (45%) | called by muse, mutect2, varscan2
- BRD4 | c.2092T>A p.F698I | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- BRWD1 | c.6614C>G p.T2205R | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BRWD1 | c.1034A>C p.D345A | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRWD3 | c.3283_3284del p.E1095Kfs*19 | Frame Shift Del (DEL) | VAF 82/286 reads (29%) | called by pindel, varscan2
- BTAF1 | c.5053C>T p.Q1685* | Nonsense Mutation (SNP) | VAF 81/214 reads (38%) | called by muse, mutect2, varscan2
- BTG1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C1GALT1C1 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C1orf68 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- C6orf118 | c.503del p.P168Lfs*15 | Frame Shift Del (DEL) | VAF 50/171 reads (29%) | called by mutect2, pindel, varscan2
- C6orf132 | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- CA1 | c.35del p.N12Mfs*34 | Frame Shift Del (DEL) | VAF 59/222 reads (27%) | called by mutect2, pindel, varscan2
- CAPN6 | c.340del p.T114Qfs*22 | Frame Shift Del (DEL) | VAF 46/218 reads (21%) | called by mutect2, pindel, varscan2
- CASP8 | c.1419del p.K473Nfs*? (on ENST00000432109 / NM_033355.3; = p.K490Nfs*? on NM_001228.4) | Frame Shift Del (DEL) | VAF 94/310 reads (30%) | called by mutect2, pindel, varscan2
- CCDC172 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2
- CCDC83 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- CCNI2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCT6B | c.1506del p.K502Nfs*9 | Frame Shift Del (DEL) | VAF 18/119 reads (15%) | called by mutect2, pindel, varscan2
- CDHR1 | c.1423C>A p.L475I | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.087); called by muse, mutect2
- CDK5R1 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDK5RAP2 | c.1413del p.K471Nfs*8 | Frame Shift Del (DEL) | VAF 54/197 reads (27%) | called by mutect2, pindel, varscan2
- CEL | c.2190del p.T731Rfs*30 (on ENST00000673714; = p.T728Rfs*30 on NM_001807.6) | Frame Shift Del (DEL) | VAF 72/240 reads (30%) | called by mutect2, pindel, varscan2
- CEP350 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP41 | c.737dup p.N246Kfs*52 | Frame Shift Ins (INS) | VAF 70/287 reads (24%) | called by mutect2, pindel, varscan2
- CFAP206 | c.1568T>C p.I523T | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2
- CFAP20DC | c.204C>T p.S68= | Splice Region (SNP) | VAF 37/87 reads (43%) | called by muse, mutect2, varscan2
- CFP | c.1095G>T p.Q365H | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.027); called by muse, mutect2
- CHD9 | c.1127A>G p.D376G | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CLEC14A | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CLEC16A | c.3091G>C p.A1031P | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC3B | c.432G>T p.W144C | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLUAP1 | c.1037-1G>A p.X346_splice | Splice Site (SNP) | VAF 62/149 reads (42%) | called by muse, mutect2, varscan2
- CLUH | c.2674del p.Q892Rfs*36 (on ENST00000435359; = p.Q931Rfs*36 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.2045G>A p.C682Y | Missense Mutation (SNP) | VAF 25/414 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COBLL1 | c.2504A>G p.Q835R (on ENST00000392717; = p.Q797R on NM_014900.5) | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- COL11A1 | c.4536G>T p.K1512N | Missense Mutation (SNP) | VAF 13/405 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CREBBP | c.6049C>G p.P2017A | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, varscan2
- CREBBP | c.5959G>T p.G1987C | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, varscan2
- CRTAC1 | c.881G>A p.G294D | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYBG2 | c.1199del p.P400Lfs*9 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- CSDC2 | c.418del p.H140Tfs*125 | Frame Shift Del (DEL) | VAF 58/177 reads (33%) | called by mutect2, pindel, varscan2
- CSMD3 | c.7972dup p.C2658Lfs*2 (on ENST00000297405 / NM_001363185.1; = p.C2554Lfs*2 on NM_052900.3) | Frame Shift Ins (INS) | VAF 28/263 reads (11%) | called by mutect2, pindel
- CSPG4 | c.1092G>T p.R364S | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); called by muse, varscan2
- CYFIP1 | c.1360-2A>G p.X454_splice | Splice Site (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- CYP2E1 | c.218del p.G73Afs*7 | Frame Shift Del (DEL) | VAF 34/150 reads (23%) | called by mutect2, pindel, varscan2
- DAB2IP | c.422G>C p.S141T (on ENST00000408936; = p.S113T on NM_032552.3) | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DCAF7 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- DCLK1 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- DDX5 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DIAPH2 | c.1891del p.M631Cfs*8 | Frame Shift Del (DEL) | VAF 23/116 reads (20%) | called by mutect2, pindel, varscan2
- DLG3 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLL1 | c.1756del p.E586Rfs*5 | Frame Shift Del (DEL) | VAF 70/270 reads (26%) | called by mutect2, varscan2
- DNAH11 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- DNAH7 | c.8194del p.I2732Lfs*15 | Frame Shift Del (DEL) | VAF 39/198 reads (20%) | called by mutect2, pindel, varscan2
- DOCK4 | c.5348G>T p.G1783V | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- DPF1 | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2
- DSEL | c.2905del p.R969Efs*16 | Frame Shift Del (DEL) | VAF 44/158 reads (28%) | called by mutect2, varscan2
- DYNC1H1 | c.12007G>A p.A4003T | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.281); called by muse, mutect2
- ECSIT | c.781del p.Q261Sfs*5 | Frame Shift Del (DEL) | VAF 70/329 reads (21%) | called by mutect2, pindel, varscan2
- EFHC1 | c.1221del p.D408Tfs*7 | Frame Shift Del (DEL) | VAF 102/370 reads (28%) | called by mutect2, pindel, varscan2
- EHMT2 | c.2145C>A p.D715E | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EIF4EBP2 | c.120del p.T41Rfs*47 | Frame Shift Del (DEL) | VAF 11/139 reads (8%) | called by mutect2, pindel
- ELAPOR1 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2
- ENAH | c.975G>T p.Q325H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen possibly damaging (0.648); called by mutect2, varscan2
- EOGT | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.046); called by muse, mutect2
- ESAM | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ESRRB | c.689del p.P230Lfs*11 | Frame Shift Del (DEL) | VAF 68/270 reads (25%) | called by mutect2, pindel, varscan2
- ETHE1 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 135/485 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EXOC3 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- F10 | c.1391G>T p.R464M | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- FAM102A | c.511C>A p.L171M (on ENST00000373095 / NM_001035254.3; = p.L29M on NM_203305.2) | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAM178B | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.178); called by muse, varscan2
- FAM214A | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 55/187 reads (29%) | called by muse, mutect2, varscan2
- FAM78B | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- FBN3 | c.6612G>A p.M2204I | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.559); called by muse, mutect2
- FBXO34 | c.358del p.I120Lfs*13 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- FGFR4 | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 31/116 reads (27%) | called by muse, mutect2, varscan2
- FIG4 | c.2077G>A p.A693T | Missense Mutation (SNP) | VAF 23/314 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2
- FLNA | c.3122A>G p.Y1041C | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FLT4 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 88/279 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- FN1 | c.1315A>G p.R439G | Missense Mutation (SNP) | VAF 96/291 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOLR3 | c.607A>G p.S203G | Missense Mutation (SNP) | VAF 110/334 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- GGA3 | c.1616dup p.L540Sfs*39 (on ENST00000537686 / NM_138619.4; = p.L507Sfs*39 on NM_014001.5) | Frame Shift Ins (INS) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 26/434 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- GGT7 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.087); called by muse, varscan2
- GH2 | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 193/570 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.138); called by muse, varscan2
- GLMP | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GNL1 | c.1229G>A p.C410Y | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGA6L9 | c.1250A>G p.H417R | Missense Mutation (SNP) | VAF 24/439 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.402); called by muse, mutect2
- GPC4 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- GPR101 | c.1253del p.L418* | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- GPR4 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- GRIN2A | c.3496C>T p.P1166S | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated, low confidence (0.8); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- GSAP | c.1603T>C p.Y535H | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- GSN | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by mutect2, varscan2
- GTF2IRD2 | c.1366G>C p.V456L | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- H1-8 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 95/218 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HBEGF | c.587del p.N196Mfs*5 | Frame Shift Del (DEL) | VAF 54/205 reads (26%) | called by mutect2, pindel, varscan2
- HEMGN | c.1345T>C p.Y449H | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.027); called by muse, mutect2
- HERC1 | c.4448del p.G1483Vfs*4 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | called by mutect2, pindel, varscan2
- HIGD2B | c.162del p.C55Afs*24 | Frame Shift Del (DEL) | VAF 28/326 reads (9%) | called by mutect2, pindel
- HMCN1 | c.15110A>G p.Y5037C | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMGN5 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HS3ST2 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 98/245 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HS6ST3 | c.1336del p.D446Tfs*24 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | called by mutect2, pindel, varscan2
- HTRA1 | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 27/367 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IFT172 | c.3774G>T p.E1258D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by mutect2, varscan2
- IKZF3 | c.1505_1507del p.G502del | In Frame Del (DEL) | VAF 15/54 reads (28%) | called by pindel, varscan2
- IL4R | c.427T>C p.W143R | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ING1 | c.1105T>C p.C369R | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ING2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- INPP5J | c.2483G>A p.S828N (on ENST00000331075 / NM_001284285.2; = p.S460N on NM_001002837.2) | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2
- IPO5 | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.325); called by muse, mutect2
- IQCF6 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- IRX3 | c.984del p.V329* | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- KAT14 | c.306del p.F102Lfs*19 | Frame Shift Del (DEL) | VAF 40/108 reads (37%) | called by mutect2, varscan2
- KDM6A | c.2300C>A p.S767Y | Missense Mutation (SNP) | VAF 131/526 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KHDRBS2 | c.623del p.G208Vfs*21 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel, varscan2
- KIAA1210 | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 80/208 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- KIDINS220 | c.4417del p.L1473Wfs*35 | Frame Shift Del (DEL) | VAF 27/87 reads (31%) | called by mutect2, pindel, varscan2
- KIFC2 | c.1731+2T>C p.X577_splice | Splice Site (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- KMT2D | c.1505_1507del p.P502del | In Frame Del (DEL) | VAF 46/159 reads (29%) | called by pindel, varscan2
- KRTAP10-9 | c.622_623del p.L208Vfs*139 | Frame Shift Del (DEL) | VAF 120/466 reads (26%) | called by mutect2, pindel, varscan2
- KXD1 | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- LARP1 | c.1978del p.D660Tfs*12 (on ENST00000518297 / NM_033551.3; = p.D583Tfs*12 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 49/152 reads (32%) | called by mutect2, pindel, varscan2
- LCOR | c.4313C>T p.A1438V | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); called by muse, mutect2
- LCP1 | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LCP2 | c.1360del p.T454Qfs*73 | Frame Shift Del (DEL) | VAF 41/158 reads (26%) | called by mutect2, pindel, varscan2
- LMO3 | c.376C>A p.L126I | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRIG1 | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.251); called by muse, mutect2
- LRRK1 | c.4979del p.G1660Afs*34 | Frame Shift Del (DEL) | VAF 20/246 reads (8%) | called by mutect2, pindel
- LRRK2 | c.1348C>T p.Q450* | Nonsense Mutation (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- LRRN3 | c.810T>A p.N270K | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRWD1 | c.955del p.E319Rfs*5 | Frame Shift Del (DEL) | VAF 47/198 reads (24%) | called by mutect2, pindel, varscan2
- LVRN | c.1384T>C p.F462L | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MAB21L1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0.196); called by muse, mutect2
- MACO1 | c.1312A>G p.K438E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- MAMDC4 | c.3173T>C p.M1058T (on ENST00000445819; = p.M979T on NM_206920.3) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- MAML3 | c.1459C>T p.Q487* | Nonsense Mutation (SNP) | VAF 129/388 reads (33%) | called by muse, varscan2
- MAP2 | c.1870A>G p.K624E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP3K4 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2
- MAST2 | c.1546A>G p.K516E | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAST3 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- MBNL1 | c.1096G>A p.A366T (on ENST00000282486 / NM_207293.2; = p.A360T on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MDN1 | c.15278dup p.N5093Kfs*6 | Frame Shift Ins (INS) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- MDN1 | c.11017del p.L3673* | Frame Shift Del (DEL) | VAF 12/116 reads (10%) | called by mutect2, pindel, varscan2
- MED12 | c.6475C>T p.Q2159* | Nonsense Mutation (SNP) | VAF 149/469 reads (32%) | called by muse, mutect2, varscan2
- MEGF6 | c.1276C>A p.H426N | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MERTK | c.344G>A p.C115Y | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIA3 | c.5288del p.P1763Lfs*9 | Frame Shift Del (DEL) | VAF 32/93 reads (34%) | called by mutect2, pindel, varscan2
- MIDN | c.541del p.D181Tfs*4 | Frame Shift Del (DEL) | VAF 24/53 reads (45%) | called by mutect2, pindel, varscan2
- MORC2 | c.2651C>T p.A884V (on ENST00000397641 / NM_001303256.3; = p.A822V on NM_014941.3) | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- MORN1 | c.358G>T p.G120* | Nonsense Mutation (SNP) | VAF 27/139 reads (19%) | called by muse, mutect2, varscan2
- MPO | c.1460A>G p.D487G | Missense Mutation (SNP) | VAF 126/373 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MSL1 | c.349dup p.E117Gfs*146 | Frame Shift Ins (INS) | VAF 18/68 reads (26%) | called by mutect2, varscan2
- MSTN | c.215T>C p.I72T | Missense Mutation (SNP) | VAF 84/316 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MSTO1 | c.1549C>T p.H517Y | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.081); called by muse, mutect2
- MTMR7 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.605); called by muse, mutect2
- MUC12 | c.11341C>A p.P3781T (on ENST00000379442; = p.P3638T on NM_001164462.1) | Missense Mutation (SNP) | VAF 96/706 reads (14%) | SIFT deleterious (0); called by muse, varscan2
- MYO18A | c.5399T>C p.L1800P | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO1G | c.3010T>A p.F1004I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYO5B | c.963T>A p.H321Q | Missense Mutation (SNP) | VAF 74/302 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, varscan2
- NAP1L5 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- NCKAP5L | c.192+8G>A | Splice Region (SNP) | VAF 75/288 reads (26%) | called by muse, mutect2, varscan2
- NCOR1 | c.6260C>T p.A2087V | Missense Mutation (SNP) | VAF 130/385 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- NES | c.1868A>C p.Q623P | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2
- NIBAN2 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.939); called by mutect2, varscan2
- NID1 | c.1634A>G p.H545R | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NKAIN1 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- NLRP5 | c.2277-1G>T p.X759_splice | Splice Site (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- NONO | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NOX5 | c.1138_1140del p.L380del | In Frame Del (DEL) | VAF 24/138 reads (17%) | called by pindel, varscan2
- NPHP4 | c.3825del p.G1277Vfs*17 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- NPHS1 | c.3190C>T p.P1064S | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.033); called by muse, mutect2
- NPR1 | c.1982T>C p.L661P | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NPW | c.28del p.A10Lfs*183 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel
- NSD1 | c.1727del p.N576Tfs*23 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | called by pindel, varscan2
- NSUN2 | c.1142C>A p.P381H | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NWD2 | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- OR2L13 | c.846dup p.M283Hfs*12 | Frame Shift Ins (INS) | VAF 58/197 reads (29%) | called by mutect2, pindel, varscan2
- OR4F15 | c.532del p.Y178Tfs*38 | Frame Shift Del (DEL) | VAF 56/137 reads (41%) | called by mutect2, pindel, varscan2
- OSBPL1A | c.1554del p.D519Tfs*56 (on ENST00000319481 / NM_080597.4; = p.D6Tfs*56 on NM_018030.4) | Frame Shift Del (DEL) | VAF 36/139 reads (26%) | called by mutect2, pindel, varscan2
- PAK6 | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PARP4 | c.4967C>T p.A1656V | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- PCCB | c.304T>C p.F102L | Missense Mutation (SNP) | VAF 103/275 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCDH9 | c.873del p.F291Lfs*15 | Frame Shift Del (DEL) | VAF 9/107 reads (8%) | called by mutect2, pindel
- PCDHB12 | c.2141G>A p.C714Y | Missense Mutation (SNP) | VAF 87/262 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PCDHGB5 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDCD11 | c.187_188del p.E63Kfs*10 | Frame Shift Del (DEL) | VAF 44/173 reads (25%) | called by pindel, varscan2
- PDIA3 | c.1014G>A p.M338I | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PFKFB3 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 33/127 reads (26%) | PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PGP | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.364); called by muse, mutect2
- PGR | c.2554C>A p.L852I | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PHC2 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PIK3C2B | c.4001dup p.I1335Hfs*3 | Frame Shift Ins (INS) | VAF 25/322 reads (8%) | called by mutect2, pindel
- PIP4K2B | c.370A>C p.S124R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2
- PLA2G4D | c.1256G>A p.G419D | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG7 | c.530+6T>C | Splice Region (SNP) | VAF 11/225 reads (5%) | called by muse, mutect2
- PML | c.1353del p.V452Cfs*82 | Frame Shift Del (DEL) | VAF 106/308 reads (34%) | called by mutect2, pindel, varscan2
- POLG | c.3425G>T p.R1142L | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- POLG | c.2210G>A p.G737E | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- POP4 | c.121del p.R41Afs*2 | Frame Shift Del (DEL) | VAF 60/176 reads (34%) | called by mutect2, pindel, varscan2
- POT1 | c.703-3del | Splice Region (DEL) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- PPEF1 | c.539T>A p.L180H | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM2 | c.443T>A p.I148K | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- PRKCZ | c.1691+3_1691+6del p.X564_splice | Splice Site (DEL) | VAF 22/98 reads (22%) | called by pindel, varscan2
- PRL | c.340A>G p.S114G | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PROSER1 | c.2835A>G p.*945Wext*16 | Nonstop Mutation (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- PRX | c.3248del p.P1083Rfs*44 | Frame Shift Del (DEL) | VAF 88/340 reads (26%) | called by mutect2, varscan2
- PSAP | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 125/315 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PTCH1 | c.3364A>G p.M1122V | Missense Mutation (SNP) | VAF 112/368 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- PTGDR2 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- PTPRJ | c.115+2_115+3del p.X39_splice | Splice Site (DEL) | VAF 20/87 reads (23%) | called by mutect2, pindel, varscan2
- PTPRZ1 | c.3059C>T p.S1020L | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- RALGAPB | c.1573dup p.C525Lfs*2 | Frame Shift Ins (INS) | VAF 61/202 reads (30%) | called by mutect2, pindel, varscan2
- RAP1GDS1 | c.1000C>T p.L334F (on ENST00000408927 / NM_001100427.2; = p.L335F on NM_021159.5) | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.312); called by muse, mutect2
- RAP2C | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); called by muse, mutect2
- RASGRF2 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- RBM12B | c.1793C>A p.P598H | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- RBM22 | c.85G>T p.G29* | Nonsense Mutation (SNP) | VAF 34/110 reads (31%) | called by muse, varscan2
- RBM47 | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 40/109 reads (37%) | called by muse, mutect2, varscan2
- RIMS2 | c.3748A>G p.S1250G | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- RIPK3 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- RNF223 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ROR1 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- RP1L1 | c.7169C>T p.A2390V | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- RP9 | c.172G>T p.G58W | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RPS6KA3 | c.2203del p.I735Sfs*66 | Frame Shift Del (DEL) | VAF 134/415 reads (32%) | called by mutect2, pindel, varscan2
- RPS8 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- RRS1 | c.1049del p.G350Vfs*20 | Frame Shift Del (DEL) | VAF 43/165 reads (26%) | called by mutect2, pindel, varscan2
- RTF1 | c.578G>T p.R193M | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- SALL3 | c.3560del p.G1187Vfs*4 | Frame Shift Del (DEL) | VAF 75/238 reads (32%) | called by mutect2, pindel, varscan2
- SAMD7 | c.709T>G p.S237A | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2
- SAP130 | c.1481del p.P494Lfs*43 | Frame Shift Del (DEL) | VAF 42/149 reads (28%) | called by mutect2, pindel, varscan2
- SBF1 | c.2396G>A p.S799N | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SCAF4 | c.887del p.P296Lfs*50 | Frame Shift Del (DEL) | VAF 12/140 reads (9%) | called by mutect2, pindel
- SCN5A | c.1320G>A p.M440I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- SCX | c.488del p.P163Rfs*27 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- SEC61A1 | c.975G>A p.S325= | Splice Region (SNP) | VAF 6/103 reads (6%) | called by muse, mutect2
- SEPTIN1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD2 | c.913del p.T305Qfs*35 | Frame Shift Del (DEL) | VAF 35/125 reads (28%) | called by mutect2, pindel, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | called by mutect2, varscan2
- SHPRH | c.277del p.S93Pfs*5 | Frame Shift Del (DEL) | VAF 20/199 reads (10%) | called by mutect2, pindel
- SIAE | c.943T>C p.F315L | Missense Mutation (SNP) | VAF 104/408 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC25A43 | c.518-1G>T p.X173_splice | Splice Site (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- SLC25A45 | c.486del p.L163Cfs*8 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | called by mutect2, pindel, varscan2
- SLC35D3 | c.673A>G p.M225V | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SLC35E4 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2
- SLC39A1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC44A2 | c.1427A>G p.Y476C | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC4A2 | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC4A8 | c.880del p.I294Ffs*26 | Frame Shift Del (DEL) | VAF 54/138 reads (39%) | called by mutect2, pindel, varscan2
- SLC52A3 | c.882del p.C295Afs*88 | Frame Shift Del (DEL) | VAF 97/373 reads (26%) | called by mutect2, pindel, varscan2
- SLC5A3 | c.78del p.F26Lfs*11 | Frame Shift Del (DEL) | VAF 28/99 reads (28%) | called by mutect2, pindel, varscan2
- SLC5A6 | c.831G>T p.Q277H | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC6A14 | c.1878del p.E627Rfs*29 | Frame Shift Del (DEL) | VAF 32/136 reads (24%) | called by pindel, varscan2
- SLFN11 | c.2368A>G p.T790A | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2
- SLITRK1 | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- SNX19 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SP5 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- SPECC1 | c.2201T>C p.V734A | Missense Mutation (SNP) | VAF 11/275 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- SPTBN1 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRCAP | c.8583del p.R2862Gfs*24 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- SUPV3L1 | c.2284C>T p.H762Y | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYCE1L | c.50A>G p.E17G | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- SYNC | c.1439-7T>G | Splice Region (SNP) | VAF 39/107 reads (36%) | called by muse, mutect2, varscan2
- SYTL2 | c.119T>A p.I40N | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- TAB1 | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TBX4 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TCF25 | c.1464A>C p.E488D | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- TCP11X2 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 137/746 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TEX15 | c.4150C>A p.L1384I (on ENST00000256246; = p.L1767I on NM_001350162.2) | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- TLR2 | c.1793T>C p.L598P | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- TMEM117 | c.898G>T p.G300C | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM234 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- TMEM236 | c.442A>G p.R148G | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM30B | c.521_523del p.F174del | In Frame Del (DEL) | VAF 23/279 reads (8%) | called by mutect2, pindel
- TMEM50A | c.52del p.E18Kfs*23 | Frame Shift Del (DEL) | VAF 74/200 reads (37%) | called by mutect2, pindel, varscan2
- TMEM68 | c.133T>G p.L45V | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMPRSS9 | c.296_297del p.E99Vfs*14 | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | called by pindel, varscan2
- TNFAIP8L3 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TP53TG5 | c.671G>T p.R224M | Missense Mutation (SNP) | VAF 85/242 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAPPC3 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TRIO | c.2095T>C p.Y699H | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRMT13 | c.627del p.V210Ffs*5 | Frame Shift Del (DEL) | VAF 39/107 reads (36%) | called by mutect2, pindel, varscan2
- TTC21A | c.2525del p.L842Cfs*14 | Frame Shift Del (DEL) | VAF 30/126 reads (24%) | called by mutect2, pindel, varscan2
- TYR | c.399A>T p.K133N | Missense Mutation (SNP) | VAF 138/409 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TYW5 | c.524del p.K175Sfs*16 | Frame Shift Del (DEL) | VAF 30/131 reads (23%) | called by mutect2, pindel, varscan2
- UBL7 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2, varscan2
- UBR4 | c.10851G>T p.K3617N | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UGP2 | c.1406del p.N469Mfs*4 | Frame Shift Del (DEL) | VAF 28/83 reads (34%) | called by mutect2, pindel, varscan2
- UNC93B1 | c.305T>C p.M102T | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- USH2A | c.4968del p.I1657Sfs*8 | Frame Shift Del (DEL) | VAF 59/277 reads (21%) | called by mutect2, pindel, varscan2
- VASN | c.1877G>A p.G626E | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- VEPH1 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VGLL1 | c.507_508del p.L171Pfs*42 | Frame Shift Del (DEL) | VAF 118/293 reads (40%) | called by mutect2, pindel, varscan2
- VILL | c.815del p.P272Hfs*2 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by mutect2, varscan2
- VPS9D1 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- VTI1B | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.022); called by muse, mutect2
- WASHC2A | c.3804T>A p.D1268E | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR11 | c.1033A>G p.S345G | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2
- WNK1 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.025); called by muse, mutect2
- XKR4 | c.1836G>T p.L612F | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- YTHDC2 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- ZBTB12 | c.919del p.A307Rfs*24 | Frame Shift Del (DEL) | VAF 34/109 reads (31%) | called by mutect2, pindel, varscan2
- ZCCHC14 | c.417A>T p.E139D (on ENST00000268616; = p.E276D on NM_015144.3) | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZDBF2 | c.542del p.P181Qfs*2 | Frame Shift Del (DEL) | VAF 49/149 reads (33%) | called by mutect2, pindel, varscan2
- ZFC3H1 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
396 further variants in this file (10 protein-altering or splice-affecting, 221 silent, 165 other) are not listed here.
